Gene-level copy-number profile of tumor specimen TCGA-50-5933-01A from TCGA case TCGA-50-5933, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 72.2 years (26,377 days).
Specimen TCGA-50-5933-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.35feda03-ee69-4b88-901f-43494711b562.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-50-5933-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1d2ed7f9-f4e9-4b29-bd58-0b48a2fe0c8e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,583; copy number 2: 24,515; copy number 3: 22,227; copy number 4: 5,068; copy number 5: 2,749; copy number 6: 913; copy number 7: 659; copy number 8: 22; copy number 9: 83.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-50-5933-01A-11D-1752-01): tumor purity 0.3, ploidy 2.82, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,426 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–175,204,849, 1,130 genes, copy number 5 (broad region; genes not listed).
- chr7:70,972–64,375,584, 1,164 genes, copy number 6–7 (broad region; genes not listed).
- chr8:38,844,866–42,897,290, 83 genes, copy number 9 (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 5–6 (broad region; genes not listed).
- chr10:72,367,327–72,626,191, 1 gene, copy number 5 (within-gene range 1–5): MICU1.
- chr10:72,467,749–85,537,483, 258 genes, copy number 5 (broad region; genes not listed).
- chr10:99,329,356–99,852,594, 16 genes, copy number 5: CNNM1, GOT1, AL391684.1, LINC01475, AL513542.1, NKX2-3, SLC25A28, AL353719.1, AL133353.1, AL133353.2, ENTPD7, EBAG9P1, CUTC, COX15, ABCC2, NANOGP6.
- chr16:30,697,707–32,003,728, 103 genes, copy number 7 (broad region; genes not listed).
- chr16:56,565,073–59,199,395, 111 genes, copy number 6–8 (broad region; genes not listed).
- chr17:69,577,251–72,237,203, 26 genes, copy number 7 (within-gene range 4–7): LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1, AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, AC007432.1, AC005144.1, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9.

Autosomal genes at a single copy (total copy number 1): 2,346. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
